Surgical pathology report (de-identified scan), TCGA case TCGA-AK-3443, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Fox Chase, specimen TCGA-AK-3443-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

Clinical History/Diagnosis: Right Renal Mass

Source of Specimen(s):

- 1: Right kidney
- 2: Portion of right adrenal

Gross Description:

Received in two parts.

Source of Tissue: 1. Labeled #1, "right kidney"

Gross Description: Received fresh in a container labeled "right kidney". It consists of a right kidney weighing 850 grams and measuring 15.0 x 11.0 x 10.5 cm. The kidney is markedly distorted from numerous bulging areas and it is grossly enlarged. Superiorly at the hilum is some residual adrenal gland measuring 1.5 x 1.0 x 0.6 cm that is otherwise unremarkable. Also at the hilum are a few tan to brown rubbery to firm nodes measuring from 0.7 up to 1.5 cm. The nodes have tan to brown cut surfaces. A segment of ureter measures 6.0 x 0.3 cm and is grossly unremarkable. Also at the hilum the vessels are unremarkable however, there is multiple bulging areas from the kidney. Perinephric fat is only present in a few areas ranging from 0.1 up to 0.5 cm. Some of the fat that is overlying some of the nodules will be submitted for histological impression. Elsewhere, the capsule overlying the presumed tumor nodules are inked black and will be submitted in relationship to the kidney lesion. The specimen is bivalved disclosing a yellowish-orange soft tumor measuring 12.0 x 9.0 x 9.5 cm comprising approximately 80% of the kidney. The tumor markedly distorts the calyceal system and is pushing into the renal pelvis and capsule. No gross invasion into the aforementioned areas is identified. Fresh tissue was prepared for [REDACTED] in the mass there is some white fibrous possible scar and an appreciable amount of hemorrhage. The adjacent uninvolved parenchyma has slight scarring and well-defined cortical-medullary junctions. Representative sections are submitted in 1A-P.

Designation of Sections: 1A- ureter and vascular margins, 1B- tumor in relationship to renal pelvis, 1C-1D- tumor in relationship to capsule, 1E- center of tumor, 1F- tumor in relationship to adjacent uninvolved kidney parenchyma, 1G- tumor overlying fat, 1H- residual adrenal gland, 1I-1J- lymph nodes, 1K-1P- additional section of tumor [REDACTED]

[page 2 of 3]
Source of Tissue: 2. Labeled #2, "portion of right adrenal"

Gross Description: Received fresh labeled, portion of right adrenal" is a 6 gram, 5.0 x 2.2 x 0.8 cm portion of adrenal gland. It is sectioned to reveal golden-yellow-orange unremarkable cut surfaces. Representative sections are submitted in two blocks.

Designation of Sections: 2A-2B

Summary of Sections: multiple

Final Diagnosis:

1. Right kidney and adrenal gland, nephrectomy and partial adrenalectomy:
- Renal oncocytic neoplasm, 12 cm, confined to renal parenchyma (see note).
- Vascular and ureteral margins, free of tumor.
- Adrenal gland, no tumor seen.
- Seven lymph nodes, no tumor seen (0/7).

Note: Immunohistochemical stains show the tumor is positive for E-Cadherin (membranous staining), many cells positive for CK7, and weakly positive for Vimentin, whereas negative for CD10, CK903, and CD117 (only cytoplasmic staining). Special stain colloidal iron shows many cells with strong, granular cytoplasmic staining. Mucicarmine special stain is negative. Differential diagnosis includes low grade chromophobe carcinoma versus atypical Oncocytoma. Cytogenetic study is pending, and the result may assist the differential diagnosis.

2. Portion of adrenal, completion of adrenalectomy:
- Adrenal gland, no tumor seen.

Procedures/Addenda

FC Cytogenetics Solid Tumor

Results-Comments

CYTOGENETIC ANALYSIS REPORTS

DIAGNOSIS: Right Renal Mass

KARYOTYPE: Normal male karyotype: 46,XY[20]

RESULTS: The renal mass was harvested after thirteen days in culture. The chromosomes from twenty metaphases were counted and analyzed, and three of these metaphases were karyotyped by G-banding. The modal chromosome number was 46, and the cells appeared to have a normal

[page 3 of 3]
karyotype. These normal results may reflect an overgrowth of normal interstitial tissue rather than tumor.

Procedures/Addenda

Addendum

Addendum Diagnosis

The cytogenetic analysis () reveals a normal () karyotype. The histomorphology is that of an atypical oncocytoma, however, foci of the tumor are strongly positive for colloidal iron, and many cells are positive for CK7. Thus, an oncocytic neoplasm with low malignant potential is favored, which is a borderline neoplasm between oncocytoma and chromophobe carcinoma.

Source: NCI Genomic Data Commons file 6a0b0eca-a6e5-43fa-a8b0-6bb5e8a25350 (TCGA-AK-3443.150D98E0-8EBA-42B4-829F-CBFF8BD01CEA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).